RC case RC-B5D4 — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/897000e3-c5eb-498c-907b-ae9e32eaa4ad

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1957; Vital status: Dead; Days to death: 2,155 days (5.9 years); Year of death: 2022; Cause of death: Cancer Related.

Diagnoses (5)
1. Prolymphocytic leukemia, T-cell type (the primary disease): ICD-O-3 morphology code: 9834/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 58.6 years (21,387 days); Year of diagnosis: 2016; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: Yes; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Bone marrow / Peripheral blood.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ruxolitinib; Initial disease status: Initial Diagnosis; Days to treatment start: 728 days (2.0 years); Days to treatment end: 788 days (2.2 years); Treatment outcome: Stable Disease; Reason treatment ended: Other; Clinical trial indicator: Yes; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab; Initial disease status: Initial Diagnosis; Days to treatment start: 804 days (2.2 years); Days to treatment end: 847 days (2.3 years); Treatment outcome: Complete Response; Reason treatment ended: Course of Therapy Completed; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Days to treatment start: 881 days (2.4 years); Treatment outcome: Complete Response; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Venetoclax; Days to treatment start: 2,098 days (5.7 years); Days to treatment end: 2,119 days (5.8 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fludarabine; Days to treatment start: 2,129 days (5.8 years); Days to treatment end: 2,131 days (5.8 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Prior malignancy of the skin (histology not recorded by GDC). Age at diagnosis: 57.4 years (20,953 days); Year of diagnosis: 2015; Days to diagnosis: -434 days (-1.2 years).
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -86 days.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Synchronous primary of the breast (histology not recorded by GDC). Laterality: Right; Age at diagnosis: 58.4 years (21,318 days); Year of diagnosis: 2016; Days to diagnosis: -69 days; AJCC staging edition: 7th; AJCC pathologic T: T1c; AJCC pathologic N: N1a; AJCC pathologic stage: Stage IIB.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 8 days; Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Anastrozole + Cyclophosphamide + Docetaxel; Days to treatment start: 63 days; Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.
4. Recurrence (histology not recorded by GDC). Age at diagnosis: 64.0 years (23,383 days); Days to diagnosis: 1,996 days (5.5 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease; Treatment outcome: Progressive Disease.
5. Progression (histology not recorded by GDC). Age at diagnosis: 64.4 years (23,513 days); Days to diagnosis: 2,126 days (5.8 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.

Follow-up (7 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90.
- Days to follow up: 915 days (2.5 years); Disease response: Tumor Free.
- Day 1,846 (end of treatment course 1): Disease response: Tumor Free.
- Day 1,996 (recurrence): Progression or recurrence: Yes; Days to progression: 1,996 days (5.5 years).
- Day 2,126 (progression): Progression or recurrence: Yes; Days to progression: 2,126 days (5.8 years).
- Days to follow up: 2,155 days (5.9 years); Karnofsky performance status: 80; ECOG performance status: 1.
- Follow-up contact recording only the day: day 1,847.

Molecular and laboratory tests
- Lactate Dehydrogenase 225 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus: Negative [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65 kg; Height: 169 cm; BMI: 22.8.
- Timepoint category: Prior to Diagnosis; Comorbidities: Hyperthyroidism / Seizure.
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 4; Tobacco smoking onset year: 1975; Tobacco smoking quit year: 1979.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample RC-B5D4-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B5D4-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
